CCDI case PBBPLS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/d48c8481-a5c4-478c-bf18-1a13894c3fe8

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Choroid plexus papilloma, NOS: ICD-O-3 morphology code: 9390/0; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.8 years (300 days).

Biospecimens (3 samples)
- Sample 0DE7CU: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DE7E3: Tissue type: Normal; Specimen type: Peripheral Whole Blood. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample 0DE7FR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
